Somatic mutation profile of tumor specimen TCGA-A7-A13F-01A (aliquot TCGA-A7-A13F-01A-11D-A12Q-09) from TCGA case TCGA-A7-A13F, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 44.8 years (16,363 days).
Specimen TCGA-A7-A13F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10d56205-4766-4a3b-837d-8050c497e981.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A13F-10A (Blood Derived Normal), aliquot TCGA-A7-A13F-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29489d57-cb55-48df-ae17-a4c1f1974f61

The open-access MAF lists 39 somatic variants for this specimen: 34 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 30, Silent 5, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB8 | c.2064G>T p.W688C (on ENST00000297504 / NM_001282291.2; = p.W671C on NM_007188.5) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52504569; called by muse, mutect2, varscan2
- ATAD2B | c.1040G>T p.R347I | Missense Mutation (SNP) | VAF 104/442 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53198630; called by muse, mutect2, varscan2
- BAZ2A | c.5479G>T p.V1827L | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs759726101, COSV51636715; called by muse, mutect2, varscan2
- BIRC6 | c.13787G>T p.S4596I | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV70199250; called by muse, mutect2, varscan2
- CALHM4 | c.842T>C p.L281S (on ENST00000368596 / NM_001366078.1; = p.L95S on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/141 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1258626760, COSV63985578; called by muse, mutect2, varscan2
- CAMKK1 | c.1004A>C p.D335A | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50116817; called by muse, mutect2, varscan2
- CNOT3 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55363240, COSV99651901; called by muse, mutect2, varscan2
- DDR2 | c.1848G>C p.K616N | Missense Mutation (SNP) | VAF 116/240 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63370917, COSV63370993, COSV63372479; called by muse, mutect2, varscan2
- DPY19L3 | c.1814G>A p.R605K | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.996); catalogued as COSV60476759; called by muse, mutect2, varscan2
- DSPP | c.1515T>A p.S505R | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV56810390; called by muse, mutect2, varscan2
- FOLH1 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 109/202 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs369440863; called by muse, mutect2, varscan2
- KCNIP2 | c.235G>A p.D79N (on ENST00000356640 / NM_173191.3; = p.D94N on NM_014591.5) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV53306712; called by muse, mutect2, varscan2
- MAGEA8 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99674324; called by muse, mutect2
- MAP3K19 | c.1247C>G p.A416G | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59638870, COSV59641213; called by muse, mutect2, varscan2
- MUC2 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.19); catalogued as rs745959654; called by muse, mutect2, varscan2
- OBSCN | c.14132T>C p.V4711A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV52773918; called by muse, mutect2
- OGFOD3 | c.352A>T p.T118S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV57340925; called by muse, mutect2, varscan2
- OLFML2B | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 74/637 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs374641911; called by muse, mutect2, varscan2
- OR5R1 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 110/225 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as rs761951903, COSV56571985, COSV56572275; called by muse, mutect2, varscan2
- PEX2 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564144139, COSV63813543; called by muse, mutect2, varscan2
- PRKCE | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 95/387 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1297022354, COSV60318529; called by muse, mutect2, varscan2
- RPGRIP1 | c.3020A>T p.H1007L | Missense Mutation (SNP) | VAF 106/147 reads (72%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV52850006; called by muse, mutect2, varscan2
- SMCR8 | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58177409; called by muse, mutect2, varscan2
- SNAI1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1237145081, COSV54864045; called by muse, mutect2, varscan2
- SORCS3 | c.2353C>A p.Q785K | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV100863342; called by muse, mutect2
- TFAP2A | c.482T>C p.V161A (on ENST00000482890; = p.V153A on NM_001032280.3) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV60233431; called by muse, mutect2, varscan2
- TRPC1 | c.1022G>A p.G341D (on ENST00000476941 / NM_001251845.2; = p.G307D on NM_003304.4) | Missense Mutation (SNP) | VAF 140/334 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs1560113574, COSV56425232; called by muse, mutect2, varscan2
- UBAP2 | c.1852G>C p.D618H | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100670787; called by muse, mutect2
- VAV1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 74/374 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs749873161, COSV58383552, COSV58390451; called by muse, mutect2, varscan2
- WDR44 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 146/428 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as COSV54163479; called by muse, mutect2, varscan2
- ZIK1 | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 21/235 reads (9%) | catalogued as rs377587068; called by muse, mutect2
- FAM169A | c.1495_1497del p.M499del | In Frame Del (DEL) | VAF 21/92 reads (23%) | called by mutect2, pindel, varscan2
- PICK1 | c.41+3_41+6del p.X14_splice | Splice Site (DEL) | VAF 20/230 reads (9%) | called by mutect2, pindel
- TENT5A | c.759_760del p.E253Dfs*20 | Frame Shift Del (DEL) | VAF 13/110 reads (12%) | called by pindel, varscan2
- BCORL1 | c.3429C>T p.S1143= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV54393143, COSV54396290; called by muse, varscan2
- GP1BA | c.1864C>T p.L622= | Silent (SNP) | VAF 42/62 reads (68%) | catalogued as COSV56699470; called by muse, mutect2, varscan2
- LTBP2 | c.3588C>T p.H1196= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs202022201, COSV56208192; called by muse, mutect2, varscan2
- NID1 | c.2622C>T p.F874= | Silent (SNP) | VAF 33/52 reads (63%) | catalogued as rs151147666, COSV99936888; called by muse, mutect2, varscan2
- SPHK2 | c.159C>T p.G53= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs754119795, COSV55337383; called by muse, mutect2, varscan2
